Gene-level copy-number profile of tumor specimen TCGA-AY-4070-01A from TCGA case TCGA-AY-4070, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 51.0 years (18,621 days).
Specimen TCGA-AY-4070-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.88ddf402-5171-4ae6-ab15-290d6b7e6ad6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AY-4070-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1db7060d-2c7b-450b-8789-b32fed606893

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1; copy number 2: 2,692; copy number 3: 17,745; copy number 4: 13,046; copy number 5: 15,691; copy number 6: 3,054; copy number 7: 1,355; copy number 8: 2,888; copy number 9: 595; copy number 10: 1,931; copy number 11: 471; copy number 12: 3; copy number 14: 234; copy number 20: 38; copy number 28: 32; copy number 80: 24; copy number 101: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AY-4070-01A-01D-1427-01): tumor purity 0.31, ploidy 4.39, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:65,319,563–65,807,435, 5 genes: EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P.
- chr16:6,380,476–6,874,005, 6 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 7,579 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:83,363,238–83,649,139, 1 gene, copy number 8 (within-gene range 4–8): SEMA3E.
- chr7:83,424,880–109,999,624, 511 genes, copy number 8–28 (broad region; genes not listed).
- chr7:110,215,891–110,216,380, 1 gene, copy number 10: AC073114.2.
- chr7:117,287,120–117,715,971, 1 gene, copy number 10 (within-gene range 6–10): CFTR.
- chr7:117,363,222–120,750,337, 21 genes, copy number 10 (within-gene range 6–10): ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7, AC002529.1, GTF3AP6, AC092098.1, AC079791.1, LINC02476, RNU1-29P, AC004946.1, AC004946.2, KCND2, RNU6-581P.
- chr7:135,926,760–148,420,998, 323 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr7:151,341,699–152,436,003, 25 genes, copy number 7–12 (within-gene range 2–12): NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5, Metazoa_SRP, GALNT11, AC006017.1, YBX1P4, KMT2C, AC104692.2, AC104692.1, SEPTIN7P6, Y_RNA.
- chr8:33,370,824–38,996,824, 109 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr8:39,018,615–39,018,683, 1 gene, copy number 8: SNORD38D.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7–11 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 8 (broad region; genes not listed).
- chr11:13,276,652–24,456,010, 192 genes, copy number 7 (broad region; genes not listed).
- chr11:26,045,987–68,284,879, 1,190 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:69,294,151–100,358,885, 646 genes, copy number 8–10 (within-gene range 5–10) (broad region; genes not listed).
- chr11:134,069,071–135,007,779, 23 genes, copy number 9 (within-gene range 5–9): JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717.
- chr13:18,467,172–34,928,076, 358 genes, copy number 7 (broad region; genes not listed).
- chr13:51,335,773–114,337,626, 734 genes, copy number 8–10 (broad region; genes not listed).
- chr17:30,529,688–30,831,318, 24 genes, copy number 80: ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1, RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8, CRLF3, AC127024.4, AC127024.5, AC127024.6, AC127024.1.
- chr17:39,687,914–39,877,896, 8 genes, copy number 101: ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr20:9,505,180–21,535,665, 196 genes, copy number 9 (broad region; genes not listed).
- chr20:23,374,519–64,313,132, 1,006 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
